Gene-level copy-number profile of tumor specimen BLGSP-71-08-00041-01B from CGCI case BLGSP-71-08-00041, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-08-00041-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83603ef9-0dcc-4256-8ea1-ca2c127a1e32.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00041-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,749 have no estimate.
https://portal.gdc.cancer.gov/files/76d726e9-43dc-4d02-aff9-b4fac3156f49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 155; copy number 1: 3,550; copy number 2: 52,174; copy number 3: 2,845; copy number 4: 128; copy number 5: 9; copy number 6: 3; copy number 10: 2; copy number 14: 2; copy number 25: 1; copy number 27: 1; copy number 30: 1; copy number 31: 3.

Homozygous deletions (total copy number 0; autosomes only): 155 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,234,912, 34 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr7:74,906,673–74,913,310, 1 gene: SPDYE12P.
- chr9:64,621,560–64,652,556, 2 genes: AQP7P2, AL445665.1.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,309,230–90,367,699, 4 genes, copy number 5–14: AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr7:75,391,955–75,410,996, 2 genes, copy number 10 (within-gene range 1–10): AC211486.1, TRIM73.
- chr9:66,721,158–66,745,929, 3 genes, copy number 31: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr14:18,333,726–18,412,264, 2 genes, copy number 5–27: CR383658.1, CR383658.2.
- chr15:43,663,654–43,684,339, 1 gene, copy number 30 (within-gene range 3–30): AC011330.1.
- chr17:46,292,733–46,337,794, 2 genes, copy number 6 (within-gene range 3–6): LRRC37A, RN7SL656P.
- chr22:21,341,595–21,396,590, 8 genes, copy number 5–25: PPP1R26P5, LINC01651, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 698. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
